Somatic mutation profile of tumor specimen MP2PRT-PARTRF-TMP1-B (aliquot MP2PRT-PARTRF-TMP1-B-1-0-D-A83C-36) from MP2PRT case MP2PRT-PARTRF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,075 days).
Specimen MP2PRT-PARTRF-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb140f80-87b7-47c2-91c6-6a4fa80f1f18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARTRF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARTRF-NB1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0581dbef-7bf8-461c-bef5-33fbf778902c

The open-access MAF lists 25 somatic variants for this specimen: 15 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 8, In Frame Ins 2, Nonsense Mutation 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ETV6 | c.1202A>G p.Y401C | Missense Mutation (SNP) | VAF 12/283 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56765551; called by muse, mutect2
- F5 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV63126602; called by muse, mutect2
- HRNR | c.5149C>T p.R1717* | Nonsense Mutation (SNP) | VAF 154/1801 reads (9%) | catalogued as rs1263607205; called by muse, varscan2
- MID2 | c.1937A>G p.D646G | Missense Mutation (SNP) | VAF 208/417 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.314); catalogued as rs1277418925; called by muse, mutect2, varscan2
- ZNF888 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766052717; called by muse, varscan2
- ABCA7 | c.5537C>G p.A1846G | Missense Mutation (SNP) | VAF 28/474 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.266); called by muse, mutect2
- AUTS2 | c.3355C>T p.R1119W | Missense Mutation (SNP) | VAF 304/636 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- IGHV4-59 | c.347_348insCCCTGGAGG p.R116delinsSPGG | In Frame Ins (INS) | VAF 20/65 reads (31%) | called by pindel, varscan2
- IGHV4-61 | c.353_354insCCCTGGAGG p.R118delinsSPGG | In Frame Ins (INS) | VAF 24/115 reads (21%) | called by pindel, varscan2
- KCNRG | c.579G>T p.R193S | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- LONRF3 | c.1289A>G p.E430G (on ENST00000371628 / NM_001031855.3; = p.E389G on NM_024778.5) | Missense Mutation (SNP) | VAF 122/275 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MS4A6E | c.398G>T p.C133F | Missense Mutation (SNP) | VAF 110/242 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2
- PLXND1 | c.5554G>C p.E1852Q | Missense Mutation (SNP) | VAF 134/281 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RINT1 | c.1508T>G p.L503R | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VPS13A | c.8447C>T p.T2816I | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA12 | c.1968G>A p.P656= (on ENST00000272895 / NM_173076.3; = p.P338= on NM_015657.3) | Silent (SNP) | VAF 64/150 reads (43%) | catalogued as rs558313663; called by muse, mutect2, varscan2
- ABCA3 | c.4617C>T p.D1539= | Silent (SNP) | VAF 233/496 reads (47%) | catalogued as rs369494610; ClinVar: likely benign; called by muse, mutect2, varscan2
- DUOX1 | c.2802G>A p.T934= | Silent (SNP) | VAF 68/173 reads (39%) | catalogued as rs1275061839, COSV58478543; called by muse, mutect2, varscan2
- FBN1 | c.3012C>T p.Y1004= | Silent (SNP) | VAF 75/330 reads (23%) | catalogued as CM145734, CM154826; called by muse, mutect2, varscan2
- PBX1 | c.714G>A p.R238= | Silent (SNP) | VAF 83/150 reads (55%) | called by muse, mutect2, varscan2
- POLH | c.384A>G p.R128= | Silent (SNP) | VAF 10/338 reads (3%) | called by muse, mutect2
- PRUNE2 | c.573T>A p.I191= | Silent (SNP) | VAF 96/250 reads (38%) | called by muse, mutect2, varscan2
- TMEM80 | c.414C>T p.H138= (on ENST00000526170 / NM_001276274.1; = p.H200= on NM_174940.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 111/649 reads (17%) | catalogued as rs146700250; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851476 G>A | 3'Flank (SNP) | VAF 121/296 reads (41%) | called by muse, mutect2, varscan2
- TRGV4 | chr7:38358511 ins GAGGGA | 5'Flank (INS) | VAF 57/129 reads (44%) | called by mutect2, pindel, varscan2
